TCGA case TCGA-61-1734 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b5e64bdb-24f1-400d-aaf7-8fda8ab6fd3c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 52.1 years (19,026 days); Year of diagnosis: 2006; Method of diagnosis: Surgical Resection; FIGO stage: Stage IC; Tumor grade: G3; Prior treatment: No; Days to last follow up: 866 days (2.4 years).
   Pathology details: Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 46 days; Days to treatment end: 158 days; Number of cycles: 6; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 866 days (2.4 years); Disease response: Tumor Free.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-61-1734-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.2; Intermediate dimension: 1; Shortest dimension: 0.3.
  Slide TCGA-61-1734-01B-01-BS1: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 99; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
  Slide TCGA-61-1734-01B-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 99; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-61-1734-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.6; Intermediate dimension: 0.6; Shortest dimension: 0.2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: Tumor free; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: Yes.
- Drug treatment 1: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free.

GDC annotations on this case (curator notes; quoted as recorded):
- Item may not meet study protocol: Pathology indicates Stage I disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 866 days; disease-specific survival: no event (censored), 866 days; disease-free interval: no event (censored), 866 days; progression-free interval: no event (censored), 866 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-61-1734-01): tumor purity 0.9, ploidy 1.94, whole-genome doublings 0 (call status: legacy_call).
